Somatic mutation profile of tumor specimen ALCH-AEOA-TTP1-A (aliquot ALCH-AEOA-TTP1-A-1-0-D-A627-36) from ALCHEMIST case ALCH-AEOA, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 78.4 years (28,643 days).
Specimen ALCH-AEOA-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a8c8f1ec-4095-41d2-907a-cf597e297898.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AEOA-NB1-A (Blood Derived Normal), aliquot ALCH-AEOA-NB1-A-1-0-D-A628-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/78cd9024-1046-466f-9585-0522e489f3d7

The open-access MAF lists 119 somatic variants for this specimen: 88 protein-altering or splice-affecting, 20 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 76, Silent 20, RNA 6, Frame Shift Del 4, Intron 3, Nonsense Mutation 3, Splice Site 2, Translation Start Site 1, In Frame Del 1, 5'UTR 1, Splice Region 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2236_2250del p.E746_A750del | In Frame Del (DEL) | VAF 574/1514 reads (38%) | hotspot (GDC flag); catalogued as rs727504233, COSV51765066, COSV51849442; ClinVar: drug response; called by mutect2, pindel, varscan2
- TP53 | c.673-2A>G p.X225_splice | Splice Site (SNP) | VAF 196/554 reads (35%) | hotspot (GDC flag); catalogued as rs1555525585, CS109519, COSV52669186, COSV52682653, COSV52687702; ClinVar: likely pathogenic / pathogenic / not provided; called by muse, mutect2, varscan2
- ADGRB3 | c.2047C>T p.H683Y | Missense Mutation (SNP) | VAF 24/365 reads (7%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as rs1418847510; called by muse, mutect2
- ADGRL3 | c.3722G>A p.R1241Q (on ENST00000506720 / NM_001322402.2; = p.R1173Q on NM_015236.6) | Missense Mutation (SNP) | VAF 56/288 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as rs143689172; called by muse, mutect2, varscan2
- ASNS | c.146G>A p.R49Q | Missense Mutation (SNP) | VAF 44/948 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs769236847, COSV99446150; ClinVar: conflicting interpretations of pathogenicity / likely pathogenic; called by muse, mutect2
- CCDC181 | c.1120A>G p.I374V | Missense Mutation (SNP) | VAF 179/497 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV100890306; called by muse, mutect2, varscan2
- CTNND2 | c.2461C>G p.Q821E | Missense Mutation (SNP) | VAF 9/136 reads (7%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.759); catalogued as rs1397485836, COSV58927187; called by muse, mutect2
- DMD | c.3655G>T p.E1219* | Nonsense Mutation (SNP) | VAF 13/283 reads (5%) | catalogued as COSV63734146; called by muse, mutect2
- GALNT14 | c.533-1G>T p.X178_splice | Splice Site (SNP) | VAF 14/223 reads (6%) | catalogued as COSV61104343; called by muse, mutect2
- GDF9 | c.792C>G p.I264M | Missense Mutation (SNP) | VAF 115/557 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.413); catalogued as rs1489719337; called by muse, mutect2, varscan2
- GLUD1 | c.43G>T p.G15W | Missense Mutation (SNP) | VAF 22/282 reads (8%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); catalogued as rs866424073; called by muse, mutect2
- HECTD1 | c.494C>A p.S165Y | Missense Mutation (SNP) | VAF 38/698 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV67947497, COSV67949500; called by muse, mutect2
- IQSEC3 | c.955G>A p.A319T (on ENST00000538872 / NM_001170738.2; = p.A16T on NM_015232.1) | Missense Mutation (SNP) | VAF 15/179 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs938290232, COSV100407434; called by muse, mutect2
- KRTAP19-7 | c.124G>T p.G42* | Nonsense Mutation (SNP) | VAF 28/738 reads (4%) | catalogued as rs1461845668; called by muse, mutect2
- LPXN | c.776G>C p.R259P | Missense Mutation (SNP) | VAF 60/204 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.664); catalogued as COSV67718100; called by muse, mutect2, varscan2
- LRRTM3 | c.542G>C p.R181P | Missense Mutation (SNP) | VAF 65/301 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63663577; called by muse, mutect2, varscan2
- MAP1B | c.2095G>A p.E699K | Missense Mutation (SNP) | VAF 44/689 reads (6%) | SIFT tolerated (0.57); PolyPhen benign (0.073); catalogued as rs1284776455; called by muse, mutect2
- MYLK | c.1523C>T p.A508V | Missense Mutation (SNP) | VAF 52/325 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs866365679; called by muse, mutect2, varscan2
- NEDD4 | c.1622G>A p.R541K (on ENST00000508342 / NM_001284338.1; = p.R122K on NM_006154.4) | Missense Mutation (SNP) | VAF 38/221 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.417); catalogued as rs141693007, COSV59064120; called by muse, mutect2, varscan2
- NEK10 | c.2122del p.E708Rfs*8 | Frame Shift Del (DEL) | VAF 23/204 reads (11%) | catalogued as COSV99835809; called by mutect2, pindel, varscan2
- NPC1 | c.1738G>A p.A580T | Missense Mutation (SNP) | VAF 18/541 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.259); catalogued as rs1295579159; called by muse, mutect2
- OR5L2 | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 8/131 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as rs868537440, COSV65723756; called by muse, mutect2
- OR6S1 | c.826G>C p.A276P | Missense Mutation (SNP) | VAF 42/1017 reads (4%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.673); catalogued as COSV57838511; called by muse, mutect2
- OR8B4 | c.541C>A p.L181I | Missense Mutation (SNP) | VAF 18/446 reads (4%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.562); catalogued as COSV62070243; called by muse, mutect2
- PAX1 | c.1461C>G p.I487M | Missense Mutation (SNP) | VAF 31/345 reads (9%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.115); catalogued as rs1410312029; called by muse, mutect2
- RBAK-RBAKDN | c.394C>T p.R132W (on ENST00000407184; = p.P111= on NM_001204513.3) | Missense Mutation (SNP) | VAF 52/204 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1010396669; called by muse, mutect2, varscan2
- RBM12 | c.560C>T p.P187L | Missense Mutation (SNP) | VAF 22/329 reads (7%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.149); catalogued as rs149544355; called by muse, mutect2
- SCP2 | c.712A>T p.S238C | Missense Mutation (SNP) | VAF 229/918 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.491); catalogued as rs1170093685; called by muse, mutect2, varscan2
- SYTL2 | c.1991G>A p.R664H (on ENST00000528231 / NM_001162951.2; = p.R640H on NM_032943.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 88/319 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as rs752868186; called by muse, mutect2, varscan2
- TMEM161B | c.1237G>A p.D413N | Missense Mutation (SNP) | VAF 46/297 reads (15%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs1396293631; called by muse, mutect2, varscan2
- UBR4 | c.11720G>A p.R3907Q | Missense Mutation (SNP) | VAF 20/400 reads (5%) | SIFT tolerated (1); PolyPhen probably damaging (0.921); catalogued as COSV64393681; called by muse, mutect2
- ZNF770 | c.1784C>T p.P595L | Missense Mutation (SNP) | VAF 67/302 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as rs1225639426; called by muse, mutect2, varscan2
- ADGRB3 | c.412T>C p.F138L | Missense Mutation (SNP) | VAF 12/324 reads (4%) | SIFT tolerated (0.65); PolyPhen benign (0.079); called by muse, mutect2
- ADGRG7 | c.610G>T p.A204S | Missense Mutation (SNP) | VAF 52/389 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ADGRV1 | c.9848T>C p.M3283T | Missense Mutation (SNP) | VAF 29/495 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.155); called by muse, mutect2
- ALDH5A1 | c.272C>T p.A91V | Missense Mutation (SNP) | VAF 218/519 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- ANKRD30A | c.3862C>A p.Q1288K (on ENST00000611781; = p.Q1232K on NM_052997.2) | Missense Mutation (SNP) | VAF 36/471 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2
- ATAD5 | c.2374del p.M792* | Frame Shift Del (DEL) | VAF 117/395 reads (30%) | called by mutect2, pindel, varscan2
- AUP1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 39/184 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- C7orf25 | c.832G>A p.E278K | Missense Mutation (SNP) | VAF 26/596 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.355); called by muse, mutect2
- CAPN6 | c.1415C>A p.T472N | Missense Mutation (SNP) | VAF 60/324 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CARD9 | c.488G>T p.R163M | Missense Mutation (SNP) | VAF 28/370 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2
- CCDC174 | c.268G>A p.A90T | Missense Mutation (SNP) | VAF 99/328 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.71); called by muse, mutect2, varscan2
- CD4 | c.64G>A p.A22T | Missense Mutation (SNP) | VAF 10/165 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.025); called by muse, mutect2
- CDC23 | c.902A>T p.D301V | Missense Mutation (SNP) | VAF 26/348 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- CRB1 | c.2985G>C p.E995D | Missense Mutation (SNP) | VAF 95/533 reads (18%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.689); called by muse, mutect2, varscan2
- CSF2RB | c.1672G>A p.A558T | Missense Mutation (SNP) | VAF 94/386 reads (24%) | SIFT tolerated (0.41); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- DBR1 | c.1305A>T p.E435D | Missense Mutation (SNP) | VAF 112/342 reads (33%) | SIFT tolerated (0.61); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAH17 | c.11842G>C p.D3948H | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- DOP1A | c.6052A>T p.M2018L | Missense Mutation (SNP) | VAF 74/263 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ERCC4 | c.332G>T p.S111I | Missense Mutation (SNP) | VAF 22/436 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2
- EXOSC10 | c.949C>A p.H317N | Missense Mutation (SNP) | VAF 50/239 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FCSK | c.1520G>A p.W507* | Nonsense Mutation (SNP) | VAF 29/149 reads (19%) | called by muse, mutect2, varscan2
- FSD2 | c.967G>C p.D323H | Missense Mutation (SNP) | VAF 54/243 reads (22%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.454); called by muse, mutect2, varscan2
- GREM2 | c.187A>C p.T63P | Missense Mutation (SNP) | VAF 45/253 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- HGFAC | c.1087del p.R363Afs*111 | Frame Shift Del (DEL) | VAF 28/299 reads (9%) | called by mutect2, pindel, varscan2
- IGKV3D-7 | c.198G>T p.Q66H | Missense Mutation (SNP) | VAF 51/567 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.166); called by muse, mutect2, varscan2
- IPMK | c.57G>T p.M19I | Missense Mutation (SNP) | VAF 37/292 reads (13%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCNC4 | c.1187C>A p.A396D | Missense Mutation (SNP) | VAF 125/495 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- LILRB5 | c.1524G>T p.Q508H (on ENST00000449561 / NM_001081442.3; = p.Q507H on NM_006840.5) | Missense Mutation (SNP) | VAF 65/265 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- LRRK1 | c.1608A>C p.A536= | Splice Region (SNP) | VAF 22/346 reads (6%) | called by muse, mutect2
- LY75 | c.195G>C p.K65N | Missense Mutation (SNP) | VAF 80/313 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- MMP27 | c.575A>G p.D192G | Missense Mutation (SNP) | VAF 20/304 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MTERF3 | c.695C>T p.S232L | Missense Mutation (SNP) | VAF 20/302 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.14); called by muse, mutect2
- MYOF | c.2733G>T p.W911C | Missense Mutation (SNP) | VAF 38/287 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NAV3 | c.5859A>T p.L1953F (on ENST00000397909 / NM_001024383.2; = p.L1931F on NM_014903.6) | Missense Mutation (SNP) | VAF 36/480 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); called by muse, mutect2
- NOD1 | c.2679A>C p.K893N | Missense Mutation (SNP) | VAF 169/483 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, varscan2
- NUP42 | c.859G>C p.A287P | Missense Mutation (SNP) | VAF 167/363 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- NUP58 | c.1228G>A p.V410I | Missense Mutation (SNP) | VAF 53/170 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.332); called by muse, mutect2, varscan2
- OR2A5 | c.133C>A p.L45M | Missense Mutation (SNP) | VAF 14/240 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2
- OR4C5 | c.194T>A p.I65N | Missense Mutation (SNP) | VAF 69/550 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.163); called by muse, mutect2, varscan2
- OR8K1 | c.513A>T p.K171N | Missense Mutation (SNP) | VAF 76/610 reads (12%) | SIFT tolerated, low confidence (0.88); PolyPhen benign (0); called by muse, mutect2, varscan2
- PAICS | c.302G>A p.R101K | Missense Mutation (SNP) | VAF 41/468 reads (9%) | PolyPhen possibly damaging (0.753); called by muse, mutect2
- PAK3 | c.1516G>A p.V506I (on ENST00000262836 / NM_001324328.2; = p.V491I on NM_002578.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/336 reads (8%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, mutect2
- PARM1 | c.877G>C p.D293H | Missense Mutation (SNP) | VAF 85/282 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLK1 | c.1231G>A p.V411I | Missense Mutation (SNP) | VAF 18/595 reads (3%) | SIFT tolerated (0.96); PolyPhen benign (0.007); called by muse, mutect2
- SGIP1 | c.749C>T p.P250L | Missense Mutation (SNP) | VAF 82/462 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- SIGLEC1 | c.887C>T p.A296V | Missense Mutation (SNP) | VAF 16/328 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.062); called by muse, mutect2
- STAT2 | c.205T>A p.Y69N | Missense Mutation (SNP) | VAF 28/460 reads (6%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2
- SUCLA2 | c.1019G>T p.G340V (on ENST00000643023; = p.G319V on NM_003850.3) | Missense Mutation (SNP) | VAF 36/564 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- TFPT | c.235C>A p.R79S | Missense Mutation (SNP) | VAF 38/169 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.363); called by mutect2, varscan2
- THBS2 | c.1628G>C p.C543S | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TIGD2 | c.892C>T p.P298S | Missense Mutation (SNP) | VAF 27/375 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); called by muse, mutect2
- TNFRSF8 | c.1417del p.H473Tfs*48 | Frame Shift Del (DEL) | VAF 88/460 reads (19%) | called by mutect2, pindel, varscan2
- USP9Y | c.1885A>G p.R629G | Missense Mutation (SNP) | VAF 52/315 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- VSNL1 | c.49G>T p.V17L | Missense Mutation (SNP) | VAF 57/404 reads (14%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- WDFY3 | c.4252G>T p.V1418L | Missense Mutation (SNP) | VAF 14/280 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.318); called by muse, mutect2
- YY1 | c.992G>C p.G331A | Missense Mutation (SNP) | VAF 19/634 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2
- B3GAT1 | c.477C>T p.R159= | Silent (SNP) | VAF 16/266 reads (6%) | catalogued as rs1247871633, COSV56998007; called by muse, mutect2
- C5orf15 | c.252C>T p.I84= | Silent (SNP) | VAF 66/353 reads (19%) | catalogued as rs1221268627; called by muse, mutect2, varscan2
- CPSF1 | c.654C>T p.L218= | Silent (SNP) | VAF 28/434 reads (6%) | catalogued as rs1026357743; called by muse, mutect2
- DGCR2 | c.117C>T p.S39= | Silent (SNP) | VAF 7/116 reads (6%) | catalogued as rs1166399589; called by muse, mutect2
- DNAH1 | c.9519C>T p.Y3173= | Silent (SNP) | VAF 136/340 reads (40%) | catalogued as rs375621008; called by muse, mutect2, varscan2
- DNAH5 | c.9516C>T p.H3172= | Silent (SNP) | VAF 77/716 reads (11%) | catalogued as rs1452202315, COSV54223297; called by muse, mutect2, varscan2
- HMCN1 | c.6078T>C p.N2026= | Silent (SNP) | VAF 30/934 reads (3%) | called by muse, mutect2
- JCAD | c.3087G>A p.G1029= | Silent (SNP) | VAF 21/259 reads (8%) | catalogued as COSV100948267; called by muse, mutect2
- MAP2 | c.2466G>T p.V822= | Silent (SNP) | VAF 12/182 reads (7%) | called by muse, mutect2
- MUC17 | c.3279C>T p.T1093= | Silent (SNP) | VAF 99/726 reads (14%) | called by muse, mutect2, varscan2
- NXN | c.849G>T p.P283= | Silent (SNP) | VAF 19/122 reads (16%) | called by muse, mutect2, varscan2
- OR11L1 | c.786C>A p.P262= | Silent (SNP) | VAF 21/440 reads (5%) | catalogued as COSV63314418; called by muse, mutect2
- POTED | c.231G>T p.T77= | Silent (SNP) | VAF 130/348 reads (37%) | catalogued as COSV55048109; called by mutect2, varscan2
- PXDNL | c.2901G>A p.L967= | Silent (SNP) | VAF 22/182 reads (12%) | called by muse, mutect2, varscan2
- RBMXL2 | c.738C>G p.S246= | Silent (SNP) | VAF 11/172 reads (6%) | called by muse, mutect2
- RNF169 | c.1035C>T p.I345= | Silent (SNP) | VAF 26/476 reads (5%) | catalogued as rs763488010; called by muse, mutect2
- SIRPB1 | c.387C>T p.D129= | Silent (SNP) | VAF 129/467 reads (28%) | catalogued as rs201140189; called by muse, mutect2, varscan2
- SNRNP200 | c.5304C>G p.P1768= | Silent (SNP) | VAF 325/937 reads (35%) | catalogued as rs1432849938; called by muse, mutect2, varscan2
- ZNF687 | c.1224C>T p.N408= | Silent (SNP) | VAF 135/572 reads (24%) | catalogued as rs763987339, COSV55016671; called by muse, mutect2, varscan2
- ZNF729 | c.1545C>A p.P515= | Silent (SNP) | VAF 155/534 reads (29%) | called by muse, mutect2, varscan2
- AC009533.1 | n.1113A>T | RNA (SNP) | VAF 66/1040 reads (6%) | called by muse, mutect2
- AMER1 | c.*3712C>T | 3'UTR (SNP) | VAF 12/162 reads (7%) | called by muse, mutect2
- FRG2B | c.-13C>G | 5'UTR (SNP) | VAF 18/266 reads (7%) | called by muse, mutect2
- GOLGA6L17P | n.30C>A | RNA (SNP) | VAF 41/671 reads (6%) | called by muse, mutect2
- KRT8P11 | n.1121C>T | RNA (SNP) | VAF 21/625 reads (3%) | called by muse, mutect2
- LEF1 | c.638+53C>A | Intron (SNP) | VAF 13/379 reads (3%) | called by muse, mutect2
- MKRN9P | n.145G>C | RNA (SNP) | VAF 10/228 reads (4%) | catalogued as rs1244884274; called by muse, mutect2
- OR1F2P | n.617C>A | RNA (SNP) | VAF 64/460 reads (14%) | catalogued as rs1348302856; called by muse, mutect2, varscan2
- SCN1A | c.4853-44G>A | Intron (SNP) | VAF 32/352 reads (9%) | catalogued as rs756116467; called by muse, mutect2
- TENM3 | c.511+102123T>C | Intron (SNP) | VAF 38/337 reads (11%) | called by muse, mutect2, varscan2
- UBTFL2 | n.107C>T | RNA (SNP) | VAF 30/394 reads (8%) | called by muse, mutect2
